Gene-level copy-number profile of tumor specimen TCGA-CH-5737-01A from TCGA case TCGA-CH-5737, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 73.2 years (26,753 days).
Specimen TCGA-CH-5737-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.ac40626a-d5d8-46eb-9beb-21aa5945919b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CH-5737-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/09e20ba9-27ef-4178-acb6-b02fb81e8e9f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 22; copy number 1: 4,814; copy number 2: 54,889; copy number 3: 12; copy number 4: 80.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CH-5737-01A-11D-1574-01): tumor purity 0.74, ploidy 1.94, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 22 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:92,410,256–92,688,254, 3 genes: AC124854.1, AC026780.1, AC026780.2.
- chr6:87,151,159–87,329,278, 5 genes: AL139274.2, ZNF292, AL139274.1, GJB7, HSPD1P10.
- chr13:38,567,715–39,603,528, 13 genes (within-gene range 0–1): LINC00366, PRDX3P3, FREM2, RNU6-56P, FREM2-AS1, PLA2G12AP2, ANKRD26P2, STOML3, PROSER1, NHLRC3, AL354809.1, NXT1P1, LHFPL6.
- chr13:66,630,715–66,630,776, 1 gene: RNU7-87P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 2,434. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
